Gene-level copy-number profile of tumor specimen MP2PRT-PARKKC-TMP1-A from MP2PRT case MP2PRT-PARKKC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,408 days).
Specimen MP2PRT-PARKKC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 926538a6-8035-432f-b7d4-3c48d889bc63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARKKC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/91870b01-3e90-47ea-9af7-190d73c3c340

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 804; copy number 2: 40,903; copy number 3: 16,460; copy number 5: 720.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,377,300–106,411,021, 5 genes (within-gene range 0–1): IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37, IGHV3-38.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,443,583, 3 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 720 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,476,737–18,494,945, 1 gene, copy number 5: LGALS9C.
- chr21:9,975,017–10,119,309, 1 gene, copy number 5 (within-gene range 3–5): CR382285.1.
- chr21:13,305,152–46,691,226, 718 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
